Somatic mutation profile of tumor specimen 1105235 (aliquot 7316UP-485-1105235) from CPTAC case C243909, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen 1105235: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5a1a8e7-3d70-4815-9de0-65a53f53b504.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105279 (Blood Derived Normal), aliquot 7316UP-219-1105279; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6abd3443-2957-4dcd-bbcd-3739c2417fa8

The open-access MAF lists 805 somatic variants for this specimen: 530 protein-altering or splice-affecting, 190 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 437, Silent 190, Nonsense Mutation 46, Intron 36, RNA 19, Frame Shift Del 19, 3'UTR 13, Splice Site 12, 5'UTR 10, Splice Region 8, 5'Flank 4, 3'Flank 3.

Variants (750 of 805; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs863225060, COSV55878075, COSV55925758; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM67 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs762543032, CM100393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>G p.C135G | Missense Mutation (SNP) | VAF 158/282 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.2486C>G p.S829* | Nonsense Mutation (SNP) | VAF 76/368 reads (21%) | catalogued as COSV52370863, COSV52383930; called by muse, mutect2, varscan2
- ANO7 | c.962C>A p.A321E (on ENST00000274979; = p.A267E on NM_001370694.2) | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375507696; called by muse, mutect2, varscan2
- ANXA13 | c.457G>C p.V153L | Missense Mutation (SNP) | VAF 84/133 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1409407846; called by muse, mutect2, varscan2
- APOB | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 97/195 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99267907; called by muse, mutect2, varscan2
- ARAP3 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1186879516; called by muse, mutect2, varscan2
- ARFGAP3 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV54311444; called by muse, mutect2, varscan2
- ARHGAP12 | c.1900C>T p.L634F | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60961844, COSV60963784; called by muse, mutect2, varscan2
- ARHGAP22 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201381170; called by muse, mutect2
- ARHGAP9 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 42/560 reads (8%) | catalogued as rs760103624, COSV57364355; called by muse, mutect2
- ASTN1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56072577; called by muse, mutect2, varscan2
- ATP6V0A2 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 95/456 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs199578524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.2995A>T p.R999* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as CD084049; called by muse, mutect2, varscan2
- C20orf144 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 172/429 reads (40%) | catalogued as rs1183825290; called by muse, mutect2, varscan2
- C2orf16 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.301); catalogued as COSV62674152; called by muse, mutect2, varscan2
- C9orf131 | c.1454T>C p.M485T | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs1380081534; called by muse, mutect2, varscan2
- CACNA1G | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as rs766099998; called by muse, mutect2, varscan2
- CACNA2D2 | c.2869C>T p.R957W (on ENST00000479441 / NM_001174051.3; = p.R950W on NM_006030.4) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1209696501, COSV99817832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALB1 | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs776542316; called by muse, mutect2, varscan2
- CAPN15 | c.2941G>T p.G981C | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54836374, COSV99562579; called by muse, mutect2, varscan2
- CBX7 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.041); catalogued as rs1442605782, COSV53358270; called by muse, mutect2
- CD163 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747001854; called by muse, mutect2, varscan2
- CDC40 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs890438403; called by muse, mutect2, varscan2
- CDH9 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV50300303; called by muse, mutect2
- CDK1 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100358872; called by muse, mutect2
- CEP85 | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs150424067; called by muse, mutect2, varscan2
- COL22A1 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV57364241; called by muse, mutect2, varscan2
- COL6A3 | c.4108G>A p.A1370T | Missense Mutation (SNP) | VAF 66/736 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as rs372234605, COSV55085755; ClinVar: uncertain significance; called by muse, mutect2
- CPLANE1 | c.7838C>G p.S2613* | Nonsense Mutation (SNP) | VAF 18/181 reads (10%) | catalogued as COSV99949726; called by muse, mutect2, varscan2
- CRACD | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs776352029; called by muse, mutect2, varscan2
- CSMD1 | c.9653C>A p.P3218Q (on ENST00000520002; = p.P3217Q on NM_033225.6) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV59306150; called by muse, mutect2
- CSMD1 | c.3701G>T p.G1234V (on ENST00000520002; = p.G1233V on NM_033225.6) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs763737608; called by muse, mutect2, varscan2
- CSMD3 | c.9299G>T p.G3100V (on ENST00000297405 / NM_001363185.1; = p.G2931V on NM_052900.3) | Missense Mutation (SNP) | VAF 174/402 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52184151; called by muse, mutect2, varscan2
- CSMD3 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 148/241 reads (61%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.023); catalogued as COSV52092277, COSV52126694; called by muse, mutect2, varscan2
- CYP46A1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99952335; called by muse, mutect2, varscan2
- DAAM1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62834150; called by muse, mutect2, varscan2
- DCDC1 | c.1633C>A p.P545T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as rs566810543; called by muse, mutect2, varscan2
- DDRGK1 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as rs200948064; called by muse, mutect2, varscan2
- DES | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 147/483 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV64660959; called by muse, mutect2, varscan2
- DGKQ | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.873); catalogued as COSV99298305; called by muse, mutect2, varscan2
- DMD | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1477425663; called by muse, mutect2, varscan2
- DST | c.2437G>A p.D813N (on ENST00000361203 / NM_001374722.1; = p.D487N on NM_001723.6) | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs367639314; called by muse, mutect2, varscan2
- DUSP10 | c.989T>A p.F330Y | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1198360310; called by muse, mutect2
- DYNC1I1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100268810, COSV61468022; called by muse, mutect2, varscan2
- EFCC1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs753804517; called by muse, mutect2, varscan2
- EOMES | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs536220570; called by muse, mutect2, varscan2
- EPHA4 | c.2197G>T p.G733W | Missense Mutation (SNP) | VAF 101/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56037210; called by muse, mutect2, varscan2
- ERGIC2 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs774859065; called by muse, mutect2, varscan2
- ETS2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV62872572; called by muse, mutect2, varscan2
- EYS | c.3684G>A p.M1228I | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58203363; called by muse, mutect2, varscan2
- F7 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 141/309 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs147680958, CM001151; called by muse, mutect2, varscan2
- FAM184B | c.371C>A p.S124* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as rs1188972903, COSV53957258; called by muse, mutect2, varscan2
- FARP2 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs777762724; called by muse, mutect2
- FGA | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs746087673, CD035514, COSV57393503, COSV57402272; called by muse, mutect2, varscan2
- FKBP1B | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as rs1431748983, COSV99272892, COSV99273018; called by muse, mutect2
- FLII | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58943841; called by muse, mutect2, varscan2
- FMR1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782759579; called by muse, varscan2
- FPGT-TNNI3K | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV100438086; called by muse, mutect2, varscan2
- FSIP2 | c.15454G>A p.E5152K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1197100532; called by muse, mutect2, varscan2
- FUT2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 68/421 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs768236330, COSV67179035; called by muse, mutect2, varscan2
- GABPA | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV61396593; called by muse, mutect2
- GATC | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV56663946; called by muse, mutect2, varscan2
- GGPS1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV51396852; called by muse, mutect2, varscan2
- GPM6A | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs1345183983; called by muse, mutect2, varscan2
- GPRASP1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 17/137 reads (12%) | catalogued as rs1294027624, COSV100851087; called by muse, mutect2, varscan2
- GRM8 | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100283592; called by muse, mutect2, varscan2
- H3C1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); catalogued as COSV55119393, COSV99772202; called by muse, mutect2, varscan2
- HCST | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs777647806; called by muse, mutect2, varscan2
- HDAC9 | c.2035C>A p.R679= | Splice Region (SNP) | VAF 57/116 reads (49%) | catalogued as COSV67786067; called by muse, mutect2, varscan2
- HOXC8 | c.312A>T p.Q104H | Missense Mutation (SNP) | VAF 59/718 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV50000548; called by muse, mutect2
- HS3ST6 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs567994936; called by muse, mutect2, varscan2
- HS6ST1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs1319053815; called by muse, mutect2, varscan2
- IGSF9B | c.1400C>A p.A467D | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100317579; called by muse, mutect2, varscan2
- IL11RA | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 121/406 reads (30%) | catalogued as rs775348905; called by muse, mutect2, varscan2
- INSYN2B | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99911494; called by muse, mutect2, varscan2
- IPP | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs780057516; called by muse, mutect2, varscan2
- IQSEC2 | c.877G>T p.A293S (on ENST00000642864 / NM_001111125.3; = p.A88S on NM_015075.2) | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV64728202; called by muse, mutect2, varscan2
- ITGBL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV66009702; called by muse, mutect2, varscan2
- IVL | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 20/351 reads (6%) | catalogued as COSV64217090; called by muse, mutect2
- KALRN | c.3252C>A p.N1084K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53785502; called by muse, mutect2, varscan2
- KCNQ3 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.548); catalogued as rs1172699877; called by muse, mutect2
- KEAP1 | c.830C>A p.T277K | Missense Mutation (SNP) | VAF 191/396 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV50262958; called by muse, mutect2, varscan2
- KLHL29 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771088004; called by muse, mutect2, varscan2
- KLRC2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs1401787503, COSV67900231; called by muse, mutect2
- KRT84 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 227/475 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1475558984; called by muse, mutect2, varscan2
- LAMA5 | c.4299C>G p.N1433K | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs576766054, COSV99439506; called by muse, mutect2
- LGALS4 | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1472907028; called by muse, mutect2, varscan2
- LRCH1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1209521446, COSV60844120; called by muse, mutect2, varscan2
- LRRC7 | c.3160C>A p.P1054T (on ENST00000651989 / NM_001370785.2; = p.P1021T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1428457255, COSV50608408; called by muse, mutect2, varscan2
- LRRFIP1 | c.1147G>A p.E383K (on ENST00000392000 / NM_001137552.2; = p.E359K on NM_004735.4) | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as rs147303790; called by muse, mutect2
- MAGEC1 | c.3098A>T p.E1033V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53581790; called by muse, mutect2
- MALRD1 | c.6098G>T p.G2033V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1423736208; called by muse, mutect2, varscan2
- MARCKS | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100893018; called by muse, mutect2, varscan2
- MGAT2 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1476271337, COSV53567037; called by muse, mutect2
- MIPOL1 | c.606G>C p.M202I | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV59390976; called by muse, mutect2, varscan2
- MMP2 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161173; called by muse, mutect2, varscan2
- MPP7 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.55); catalogued as rs762252605, COSV61739431; called by muse, mutect2, varscan2
- MUC17 | c.9346C>A p.P3116T | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.341); catalogued as rs562321094; called by muse, mutect2, varscan2
- MUC22 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious, low confidence (0.01); catalogued as rs1225649659, COSV73736210; called by muse, mutect2, varscan2
- MYO10 | c.3239G>A p.G1080E | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.034); catalogued as COSV99946185; called by muse, mutect2
- N6AMT1 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs757481872; called by muse, mutect2, varscan2
- NBPF10 | c.1976C>G p.A659G | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.333); catalogued as rs782224083; called by muse, mutect2
- NEFL | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563251398, COSV99648163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.268); catalogued as COSV52568451; called by muse, mutect2
- NLRP1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 191/487 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs145709003; called by mutect2, varscan2
- NLRP5 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs372305298, COSV66768008; called by muse, mutect2, varscan2
- NPBWR2 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.14); catalogued as COSV63900403; called by muse, mutect2, varscan2
- NPY1R | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV56714298, COSV56715481; called by muse, mutect2, varscan2
- NRBP1 | c.1268C>G p.P423R | Missense Mutation (SNP) | VAF 166/380 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV51993925; called by muse, mutect2, varscan2
- NTRK1 | c.354T>A p.S118R | Missense Mutation (SNP) | VAF 101/689 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as CD087748; called by muse, mutect2, varscan2
- OLFML2A | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202197796; called by muse, mutect2, varscan2
- OR14A16 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1374004830; called by muse, mutect2, varscan2
- OR2T33 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58815134; called by muse, mutect2, varscan2
- OR4A16 | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV59045243, COSV59045505; called by muse, mutect2, varscan2
- OR51B2 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs758948105; called by muse, mutect2, varscan2
- P3H1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 95/262 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs200935208; called by muse, mutect2, varscan2
- PASD1 | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.224); catalogued as rs773014348; called by muse, mutect2, varscan2
- PCDHB13 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 92/341 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53393831; called by muse, mutect2, varscan2
- PCDHGB1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs551145874, COSV53913385; called by muse, mutect2, varscan2
- PCDHGB5 | c.2397+4A>T | Splice Region (SNP) | VAF 24/104 reads (23%) | catalogued as rs764084750; called by muse, mutect2, varscan2
- PCNX2 | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237031185, COSV99265907; called by muse, mutect2, varscan2
- PGAP6 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51739093; called by muse, mutect2
- PGK2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165222; called by muse, mutect2, varscan2
- PI3 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 41/526 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs148103941, COSV54783624; called by muse, mutect2
- PIN4 | c.353C>A p.P118Q (on ENST00000664196; = p.P93Q on NM_006223.4) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1423088655, COSV54485019; called by muse, mutect2, varscan2
- PLCE1 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs754933489, COSV53357882; called by muse, mutect2, varscan2
- POTEA | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.731); catalogued as rs527259841; called by muse, mutect2, varscan2
- PPP1R21 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV54289978; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- PSG9 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 107/187 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs749016381; called by muse, mutect2, varscan2
- PSMD3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 116/319 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs555631976; called by muse, mutect2, varscan2
- PTF1A | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1325439993; called by muse, mutect2, varscan2
- PTPRD | c.3886G>T p.E1296* | Nonsense Mutation (SNP) | VAF 32/77 reads (42%) | catalogued as COSV61926583, COSV61978921; called by muse, mutect2, varscan2
- PXDNL | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs754362945; called by muse, mutect2, varscan2
- PXDNL | c.886A>T p.R296* | Nonsense Mutation (SNP) | VAF 29/141 reads (21%) | catalogued as COSV62487640; called by muse, mutect2, varscan2
- QTRT2 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as rs764847068; called by muse, mutect2
- RAB3IL1 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as rs749370411; called by muse, mutect2, varscan2
- RASA2 | c.502A>G p.T168A | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs770448162; called by muse, mutect2, varscan2
- RHAG | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs755021125, COSV57702987; called by muse, mutect2, varscan2
- RIOX1 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1003703772; called by muse, mutect2
- RNF115 | c.704A>T p.Y235F | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs782790501; called by muse, mutect2, varscan2
- RPTN | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 141/425 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60169158; called by muse, mutect2, varscan2
- RRM1 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); catalogued as rs779004662; called by muse, mutect2, varscan2
- RTN1 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV50718699, COSV50719661; called by muse, mutect2, varscan2
- RYR2 | c.9460G>T p.A3154S | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV63677166; called by muse, mutect2, varscan2
- RYR3 | c.4541G>T p.R1514L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV66776059; called by muse, mutect2, varscan2
- SCARA5 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 41/311 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs765093547; called by muse, mutect2, varscan2
- SCN5A | c.1726C>G p.P576A | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.055); catalogued as COSV61133873; called by mutect2, varscan2
- SEMA4A | c.1587del p.N530Tfs*2 | Frame Shift Del (DEL) | VAF 16/121 reads (13%) | catalogued as rs1558163897; called by mutect2, pindel
- SERPINA4 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 46/575 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs745567923; called by muse, mutect2
- SF3A1 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99305781; called by muse, mutect2, varscan2
- SKOR1 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs943427929, COSV58250085; called by muse, mutect2, varscan2
- SLC3A1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.161); catalogued as rs753527558, COSV53224516; called by muse, mutect2, varscan2
- SLC4A3 | c.2731C>A p.R911S | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56093013; called by muse, mutect2, varscan2
- SLC5A11 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 139/254 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs932697713, COSV61741032; called by muse, mutect2, varscan2
- SP3 | c.1334C>G p.P445R | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100022002; called by muse, mutect2, varscan2
- SPATA31A6 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 65/527 reads (12%) | catalogued as COSV60534229; called by muse, mutect2, varscan2
- SPATA31E1 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV57789559; called by muse, mutect2, varscan2
- SPTA1 | c.3189-1G>A p.X1063_splice | Splice Site (SNP) | VAF 36/276 reads (13%) | catalogued as COSV63760610; called by muse, mutect2, varscan2
- SRCAP | c.6724G>A p.E2242K | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52679522; called by muse, mutect2
- SRCAP | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as rs1386993634; called by muse, mutect2
- STAB1 | c.7091C>A p.T2364K | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV100195323; called by muse, mutect2, varscan2
- STXBP5L | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV56510181, COSV56514530; called by muse, mutect2, varscan2
- SUGCT | c.1196G>T p.R399M (on ENST00000335693 / NM_001193313.2; = p.R425M on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/191 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100000648; called by muse, mutect2, varscan2
- SULF1 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201774043, COSV52690552; called by muse, mutect2, varscan2
- SVEP1 | c.1876del p.A626Qfs*25 | Frame Shift Del (DEL) | VAF 39/97 reads (40%) | catalogued as COSV57049750; called by mutect2, pindel, varscan2
- SYNE1 | c.16868G>A p.R5623H (on ENST00000367255 / NM_182961.4; = p.R5552H on NM_033071.3) | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs753544584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBCK | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs35784409; called by muse, mutect2, varscan2
- TENT5D | c.275C>A p.P92Q | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV57638237; called by muse, mutect2, varscan2
- TG | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 166/371 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV55071873; called by muse, mutect2, varscan2
- TLL2 | c.2630A>G p.Q877R | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1287812731; called by muse, mutect2, varscan2
- TMC5 | c.1388C>T p.S463L (on ENST00000396229 / NM_001105248.1; = p.S217L on NM_024780.5) | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as rs774954657; called by muse, mutect2, varscan2
- TMC5 | c.1635C>T p.F545= (on ENST00000396229 / NM_001105248.1; = p.F299= on NM_024780.5) | Splice Region (SNP) | VAF 12/112 reads (11%) | catalogued as COSV99060519; called by muse, mutect2
- TMEM200A | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1331253259; called by muse, mutect2, varscan2
- TMEM260 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99839844; called by muse, mutect2
- TNN | c.412C>T p.L138= | Splice Region (SNP) | VAF 25/214 reads (12%) | catalogued as COSV53420870; called by muse, mutect2, varscan2
- TRAJ53 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | PolyPhen probably damaging (0.944); catalogued as rs900687390; called by muse, mutect2, varscan2
- TRIM10 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV100939565; called by muse, mutect2, varscan2
- TRIM58 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1201819173; called by muse, mutect2, varscan2
- TRIM7 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.118); catalogued as rs954710762; called by muse, mutect2, varscan2
- TRPC5 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53285039; called by muse, mutect2, varscan2
- TTC6 | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.935); catalogued as rs1288417845; called by muse, mutect2, varscan2
- UBR2 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as COSV65749302; called by muse, mutect2, varscan2
- UNC13C | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV52891998; called by muse, mutect2
- USH2A | c.13561C>G p.P4521A | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV56406267; called by muse, mutect2, varscan2
- USH2A | c.9226G>T p.D3076Y | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56401181, COSV56439100; called by muse, mutect2, varscan2
- USP6 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs750862063; called by muse, mutect2, varscan2
- VAT1L | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758626119, COSV56817365; called by muse, mutect2
- VAV3 | c.1545C>A p.D515E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58377874; called by muse, mutect2, varscan2
- VMP1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs368929171; called by muse, mutect2, varscan2
- VPS13B | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1169113054; called by muse, mutect2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 34/413 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, mutect2
- WSCD2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753595241; called by mutect2, varscan2
- ZEB2 | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100355670; called by muse, mutect2, varscan2
- ZFHX3 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs760180670; called by muse, mutect2, varscan2
- ZFPM1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV60324082; called by muse, mutect2, varscan2
- ZFYVE9 | c.2357T>C p.I786T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as rs1006288970; called by muse, mutect2
- ZIC5 | c.1150T>C p.F384L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs913484014; called by muse, mutect2, varscan2
- ZNF232 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs745741402; called by muse, mutect2, varscan2
- ZNF438 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs199999473, COSV59194055; called by muse, mutect2, varscan2
- ZNF514 | c.205G>T p.G69* | Nonsense Mutation (SNP) | VAF 60/105 reads (57%) | catalogued as COSV99727697; called by muse, mutect2, varscan2
- ZNF705A | c.254A>T p.K85M | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs1424881100; called by muse, mutect2, varscan2
- ZNF784 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1225390047; called by muse, mutect2, varscan2
- ZP4 | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs376995776; called by muse, mutect2, varscan2
- ZSCAN1 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 47/295 reads (16%) | catalogued as rs761346628, COSV56609383; called by muse, mutect2, varscan2
- ABCC9 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACOX1 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM23 | c.1912G>A p.G638R | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS1 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAMTS1 | c.1608A>C p.E536D | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.745T>C p.C249R | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRA3 | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, varscan2
- ADGRE1 | c.1960G>T p.A654S | Missense Mutation (SNP) | VAF 69/119 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- AGXT2 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 53/623 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ALPK3 | c.4452C>G p.I1484M | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMER1 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- AMY2B | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANK1 | c.3575C>A p.T1192N | Missense Mutation (SNP) | VAF 111/359 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- APOL3 | c.270A>C p.R90S (on ENST00000349314 / NM_145640.2; = p.R19S on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2
- ARL6IP4 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARMC4 | c.2007C>G p.I669M | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARMT1 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP10B | c.2444T>A p.L815Q | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1547A>T p.Q516L | Missense Mutation (SNP) | VAF 233/566 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATP6V1G3 | c.27C>A p.H9Q | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- B3GLCT | c.231A>C p.L77F | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- BAIAP2L1 | c.955+7G>A | Splice Region (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- C10orf88 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C12orf66 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- C17orf99 | c.369C>A p.S123= | Splice Region (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- C2orf16 | c.543G>C p.L181F | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.31); called by muse, mutect2
- CACNA1D | c.1299G>T p.E433D | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CADM2 | c.613G>C p.V205L (on ENST00000407528 / NM_001167674.2; = p.V207L on NM_153184.4) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CALD1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CAMTA2 | c.2464C>A p.P822T | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CCDC168 | c.7754G>T p.G2585V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC171 | c.3031C>A p.L1011I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC89 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCL3 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 69/340 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CCNB3 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH23 | c.8641G>T p.V2881F | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CDHR1 | c.1117del p.Q373Rfs*42 | Frame Shift Del (DEL) | VAF 24/232 reads (10%) | called by mutect2, pindel, varscan2
- CENPJ | c.2769G>C p.E923D | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFAP221 | c.1784C>A p.S595Y | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CFAP47 | c.2128T>A p.S710T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CFAP47 | c.6914G>T p.R2305L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP94 | c.1164G>T p.L388F (on ENST00000320267 / NM_001352064.2; = p.L394F on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- CHD4 | c.4901A>G p.E1634G (on ENST00000357008 / NM_001363606.2; = p.E1645G on NM_001273.5) | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CHD6 | c.3322G>T p.G1108C | Missense Mutation (SNP) | VAF 65/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD7 | c.3172T>A p.L1058M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CHD8 | c.1922C>T p.A641V (on ENST00000646647 / NM_001170629.2; = p.A362V on NM_020920.4) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CHL1 | c.2569G>A p.D857N (on ENST00000397491 / NM_001253387.1; = p.D873N on NM_006614.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CLDN14 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 56/200 reads (28%) | called by muse, mutect2, varscan2
- CLEC1A | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CLEC3A | c.488G>A p.W163* (on ENST00000651443; = p.W154* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 49/329 reads (15%) | called by muse, mutect2, varscan2
- CLSPN | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CMTR1 | c.48G>C p.Q16H | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNPY3 | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 28/156 reads (18%) | called by muse, varscan2
- COL4A2 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COP1 | c.652A>T p.R218W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- CORIN | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPAMD8 | c.1037G>A p.C346Y (on ENST00000651564; = p.C299Y on NM_015692.5) | Missense Mutation (SNP) | VAF 107/195 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE8 | c.261dup p.E88* | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- CRP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CSMD1 | c.9652C>A p.P3218T (on ENST00000520002; = p.P3217T on NM_033225.6) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.426); called by muse, mutect2
- CSMD1 | c.5796C>A p.Y1932* (on ENST00000520002; = p.Y1931* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 43/173 reads (25%) | called by muse, mutect2, varscan2
- CTAGE9 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CYP2R1 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- DACH1 | c.917del p.P306Rfs*12 | Frame Shift Del (DEL) | VAF 34/88 reads (39%) | called by mutect2, pindel, varscan2
- DDX60L | c.4606G>C p.E1536Q | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DGAT1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- DHDDS | c.951G>C p.L317F (on ENST00000236342 / NM_001319959.1; = p.L318F on NM_024887.3) | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNAH3 | c.5392G>A p.A1798T | Missense Mutation (SNP) | VAF 63/255 reads (25%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK10 | c.3126C>G p.Y1042* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- DSG2 | c.1185T>G p.I395M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- EEF1D | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- EIF2S2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2
- EIF4E2 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- EYS | c.6328A>T p.N2110Y | Missense Mutation (SNP) | VAF 103/276 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FAM169A | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- FAM209B | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 130/531 reads (24%) | called by muse, mutect2, varscan2
- FAM47A | c.744_747del p.P249Gfs*16 | Frame Shift Del (DEL) | VAF 50/242 reads (21%) | called by mutect2, pindel, varscan2
- FAM50B | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- FAP | c.2250C>A p.H750Q | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FASN | c.5992G>C p.G1998R | Missense Mutation (SNP) | VAF 286/728 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT1 | c.6135G>T p.E2045D | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAT2 | c.7383C>A p.F2461L | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAXC | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FCN1 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 37/292 reads (13%) | called by muse, mutect2, varscan2
- FCRL1 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- FER1L6 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- FER1L6 | c.5174C>A p.A1725D | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FGF13 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 159/286 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGG | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FMN2 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXC2 | c.1127C>G p.A376G | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRMPD2 | c.2273A>T p.K758M | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- FYB1 | c.89C>G p.S30* | Nonsense Mutation (SNP) | VAF 94/530 reads (18%) | called by muse, mutect2, varscan2
- GAK | c.569G>C p.C190S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GATA4 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 61/341 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- GCLC | c.1401+1G>T p.X467_splice (on ENST00000643939; = p.X465_splice on NM_001498.4) | Splice Site (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- GEN1 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFRA4 | c.473C>T p.A158V (on ENST00000319242 / NM_145762.3; = p.P132S on NM_022139.4) | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GIP | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GK3P | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- GMPR | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GOLGA6L4 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GPBP1 | c.756T>G p.F252L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GPC6 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- GPR149 | c.981+2T>C p.X327_splice | Splice Site (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- GPR50 | c.1800C>A p.Y600* | Nonsense Mutation (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- GYS2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HAP1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HCK | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELZ | c.4327C>A p.P1443T | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HHIPL2 | c.2133G>T p.R711S | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIPK3 | c.2035A>T p.T679S | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HMX1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNF1B | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- HOXC13 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.931); called by muse, mutect2
- HRNR | c.1672T>A p.Y558N | Missense Mutation (SNP) | VAF 90/946 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2
- HSF2 | c.66C>A p.H22Q | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ICAM3 | c.1206T>G p.I402M | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- IFT140 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- IGF1R | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 113/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-17 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 158/420 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- IGLV3-19 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- IGSF3 | c.1629G>A p.M543I (on ENST00000369486 / NM_001007237.3; = p.M563I on NM_001542.4) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGSF5 | c.140dup p.N47Kfs*29 | Frame Shift Ins (INS) | VAF 25/160 reads (16%) | called by mutect2, varscan2
- INPP4B | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- INSC | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- INTS3 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2
- ITGB1 | c.1432C>A p.H478N | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ITSN2 | c.3178G>C p.V1060L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- JMJD1C | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KAT6B | c.4303G>T p.E1435* | Nonsense Mutation (SNP) | VAF 61/427 reads (14%) | called by muse, mutect2, varscan2
- KCND2 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KCNH7 | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNJ15 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNQ2 | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 37/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNU1 | c.2746A>C p.N916H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KIAA1671 | c.5032G>A p.E1678K | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KLHL29 | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LCE1D | c.140G>C p.C47S | Missense Mutation (SNP) | VAF 68/502 reads (14%) | PolyPhen probably damaging (0.978); called by muse, varscan2
- LCOR | c.379A>T p.K127* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | called by muse, varscan2
- LHCGR | c.779C>A p.P260Q | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LMLN | c.404del p.R135Hfs*111 | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | called by mutect2, pindel, varscan2
- LMTK3 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- LPAR5 | c.974C>A p.T325K | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRBA | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC70 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LTBP2 | c.4228C>A p.R1410S | Missense Mutation (SNP) | VAF 301/630 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- MAB21L1 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- MAFB | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 151/534 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB6B | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 56/264 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- MAGEB6B | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 66/217 reads (30%) | called by muse, mutect2, varscan2
- MAP3K6 | c.2542C>T p.P848S | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCO | c.1556G>T p.S519I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, varscan2
- MBD5 | c.1002A>T p.Q334H | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCAT | c.512-2A>T p.X171_splice | Splice Site (SNP) | VAF 47/131 reads (36%) | called by muse, mutect2, varscan2
- MEF2C | c.237del p.T80Qfs*9 | Frame Shift Del (DEL) | VAF 41/141 reads (29%) | called by mutect2, pindel, varscan2
- MEIS1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 145/242 reads (60%) | SIFT tolerated (0.76); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MINDY4B | c.824+1G>T p.X275_splice | Splice Site (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- MOGAT2 | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- MORC1 | c.2284C>A p.L762I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MRC2 | c.1569+1G>T p.X523_splice | Splice Site (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- MRM1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSLNL | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- MSMB | c.207T>A p.C69* | Nonsense Mutation (SNP) | VAF 47/140 reads (34%) | called by muse, mutect2, varscan2
- MTOR | c.4002G>T p.Q1334H | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MTUS2 | c.2308C>G p.L770V | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC22 | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2
- MUC5B | c.6518G>A p.S2173N | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.878); called by muse, mutect2
- MXRA5 | c.2559C>A p.H853Q | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO7B | c.642del p.K215Sfs*12 | Frame Shift Del (DEL) | VAF 94/278 reads (34%) | called by mutect2, pindel, varscan2
- MYRF | c.1700C>T p.P567L (on ENST00000278836 / NM_001127392.3; = p.P558L on NM_013279.4) | Missense Mutation (SNP) | VAF 120/432 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- N4BP2L2 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEBL | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- NF1 | c.5383G>A p.D1795N (on ENST00000358273 / NM_001042492.3; = p.D1774N on NM_000267.3) | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- NLN | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRAS | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NUP153 | c.4322C>A p.S1441Y | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2
- NUP153 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NUP155 | c.723+2T>G p.X241_splice (on ENST00000231498 / NM_153485.3; = p.X182_splice on NM_004298.4) | Splice Site (SNP) | VAF 23/259 reads (9%) | called by muse, mutect2
- NXPE3 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OGDHL | c.1422C>G p.C474W | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13F1 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- OR2AT4 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- OR2C3 | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- OR3A2 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 67/172 reads (39%) | called by muse, mutect2, varscan2
- OR4C11 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR4K1 | c.896G>T p.W299L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52D1 | c.197del p.L66Pfs*68 | Frame Shift Del (DEL) | VAF 21/143 reads (15%) | called by mutect2, pindel, varscan2
- OR5L2 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- OR6B2 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR6K6 | c.140A>T p.H47L (on ENST00000368144; = p.H23L on NM_001005184.1) | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOGL | c.6337G>T p.D2113Y (on ENST00000547103; = p.D2104Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OTUD7A | c.1365G>C p.E455D (on ENST00000307050 / NM_001382637.1; = p.E448D on NM_130901.3) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PALLD | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 100/488 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PARD3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCDHA12 | c.2308A>T p.M770L | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDHGA9 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PCDHGB6 | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PDE7B | c.492_494del p.E164del | In Frame Del (DEL) | VAF 26/104 reads (25%) | called by pindel, varscan2
- PDE9A | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PGAP6 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHKA2 | c.1270del p.D424Ifs*3 | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel, varscan2
- PKD1 | c.7042A>G p.K2348E | Missense Mutation (SNP) | VAF 138/431 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PKD1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLBD2 | c.860-1G>T p.X287_splice | Splice Site (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- PLBD2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PLCB1 | c.3440A>T p.E1147V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.536); called by muse, mutect2
- PLEKHG4B | c.2261G>T p.G754V (on ENST00000283426; = p.G1110V on NM_052909.5) | Missense Mutation (SNP) | VAF 152/582 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PLEKHG4B | c.2909C>T p.A970V (on ENST00000283426; = p.A1326V on NM_052909.5) | Missense Mutation (SNP) | VAF 26/517 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLG | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLOD3 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 137/439 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLPPR4 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2
- PLRG1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.028); called by muse, mutect2
- PLSCR3 | c.725del p.G242Afs*23 | Frame Shift Del (DEL) | VAF 56/319 reads (18%) | called by mutect2, pindel, varscan2
- PLSCR3 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- POF1B | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- POM121L12 | c.45dup p.W16Lfs*130 | Frame Shift Ins (INS) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- POTEA | c.917A>G p.K306R (on ENST00000519951 / NM_001005365.2; = p.K260R on NM_001002920.1) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- POU3F3 | c.879C>A p.H293Q | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by mutect2, varscan2
- PRB1 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, varscan2
- PRDM5 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PRKCB | c.169A>T p.I57F | Missense Mutation (SNP) | VAF 87/491 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- PTCH2 | c.3134G>A p.G1045D | Missense Mutation (SNP) | VAF 130/433 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2B | c.1917G>C p.E639D | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PTTG1 | c.520T>A p.W174R | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- QRICH1 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RAD51AP2 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- RASGRP4 | c.1708C>A p.R570S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASIP1 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBM15 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RBM15 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RBM15B | c.832del p.R278Vfs*50 | Frame Shift Del (DEL) | VAF 42/265 reads (16%) | called by mutect2, pindel, varscan2
- RFX7 | c.635G>C p.R212P (on ENST00000559447 / NM_001368074.1; = p.R309P on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RNF148 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RSRC2 | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SAP130 | c.2988+1G>T p.X996_splice | Splice Site (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- SAXO1 | c.749A>T p.E250V | Missense Mutation (SNP) | VAF 127/227 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SCG2 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SCRT1 | c.32A>G p.K11R | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SEL1L3 | c.2670-1G>T p.X890_splice | Splice Site (SNP) | VAF 12/70 reads (17%) | called by muse, varscan2
- SENP7 | c.1614_1615del p.V540Yfs*8 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- SETD4 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHPRH | c.1047_1051del p.N349Kfs*8 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel*
- SIPA1L2 | c.1996A>G p.T666A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SLC22A24 | c.1349A>T p.N450I | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- SLC2A12 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC2A13 | c.1557_1559del p.F520del | In Frame Del (DEL) | VAF 10/93 reads (11%) | called by pindel, varscan2
- SLC8A1 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO5A1 | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SMG5 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 33/363 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2
- SMYD5 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 166/279 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX30 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SOD3 | c.417C>A p.H139Q | Missense Mutation (SNP) | VAF 259/595 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRGAP1 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- STAB1 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- STYXL2 | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SUCNR1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP1 | c.194del p.P65Hfs*30 | Frame Shift Del (DEL) | VAF 94/188 reads (50%) | called by mutect2, pindel
- SVEP1 | c.5924C>G p.T1975R | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- SYNE2 | c.2623G>T p.G875C | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- TAF15 | c.376C>T p.Q126* (on ENST00000605844 / NM_139215.3; = p.Q123* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | called by muse, mutect2, varscan2
- TBK1 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- TCP10L | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TDRD15 | c.4418C>A p.S1473* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- TESPA1 | c.190T>C p.W64R | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFAP4 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 86/455 reads (19%) | called by muse, mutect2, varscan2
- TFDP3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- THNSL2 | c.961A>T p.N321Y | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.4192G>T p.G1398C (on ENST00000272643; = p.G1396C on NM_001316349.2) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIGD2 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TLR6 | c.1665G>T p.W555C | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLR8 | c.1473C>G p.N491K (on ENST00000218032 / NM_138636.5; = p.N509K on NM_016610.4) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM237 | c.1172C>A p.S391Y (on ENST00000409883 / NM_001044385.3; = p.S383Y on NM_152388.4) | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2
- TMEM263 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TMEM40 | c.418_424+17del p.X140_splice | Splice Site (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel
- TOP2B | c.4468A>G p.K1490E (on ENST00000264331 / NM_001330700.2; = p.K1485E on NM_001068.3) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRHDE | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- TRIM58 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2
- TRIM60 | c.275_278del p.K92Rfs*12 | Frame Shift Del (DEL) | VAF 12/127 reads (9%) | called by mutect2, pindel, varscan2
- TRIM69 | c.1460G>T p.G487V (on ENST00000329464 / NM_182985.5; = p.G328V on NM_080745.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, varscan2
- TRPS1 | c.1127A>T p.E376V (on ENST00000220888 / NM_001330599.2; = p.E389V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- TRPS1 | c.1126G>T p.E376* (on ENST00000220888 / NM_001330599.2; = p.E389* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/235 reads (20%) | called by muse, mutect2, varscan2
- TSC2 | c.2286G>T p.L762F | Missense Mutation (SNP) | VAF 138/410 reads (34%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPYL2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 90/402 reads (22%) | called by muse, mutect2, varscan2
- TTC6 | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTLL13P | c.2318C>G p.S773* | Nonsense Mutation (SNP) | VAF 44/276 reads (16%) | called by muse, mutect2, varscan2
- UBR3 | c.5576A>T p.K1859M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- UNC45B | c.2605C>A p.L869M | Missense Mutation (SNP) | VAF 76/355 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC5D | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- UNC79 | c.4549C>A p.H1517N (on ENST00000393151 / NM_001346218.2; = p.H1340N on NM_020818.5) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- USP17L1 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 80/482 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- USP48 | c.1451-3C>G | Splice Region (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- UTP18 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VIRMA | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- VPS13B | c.3984G>C p.W1328C | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- VPS45 | c.522G>C p.M174I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- VWA5B1 | c.2223C>G p.C741W | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- WDFY4 | c.4052C>A p.A1351D | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WDR43 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by mutect2, varscan2
- WEE2 | c.243G>C p.L81F | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WWC2 | c.535_538del p.K179Efs*6 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- XAGE5 | c.115del p.E39Kfs*89 | Frame Shift Del (DEL) | VAF 41/140 reads (29%) | called by mutect2, pindel, varscan2
- XIRP2 | c.2256T>A p.D752E (on ENST00000628543; = p.D927E on NM_152381.6) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XKR6 | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- YIPF6 | c.594C>A p.A198= | Splice Region (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- ZAN | c.6200G>T p.G2067V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ZBTB21 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- ZC3H15 | c.93G>C p.L31F | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZFP82 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ZIC5 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 200/422 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF257 | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 86/149 reads (58%) | called by muse, mutect2, varscan2
- ZNF441 | c.1510A>T p.K504* | Nonsense Mutation (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- ZNF521 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ZNF600 | c.503del p.G168Afs*10 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by mutect2, varscan2
- ZNF623 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ZNF626 | c.102A>T p.L34F | Missense Mutation (SNP) | VAF 126/184 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZNF638 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 31/209 reads (15%) | PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZNF679 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF699 | c.1928A>C p.*643Sext*2 | Nonstop Mutation (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- ZNF804A | c.3503A>T p.Q1168L | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF831 | c.4529G>T p.S1510I | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF853 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ACSM2A | c.1212C>A p.P404= (on ENST00000219054; = p.P325= on NM_001308169.2) | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV54584720; called by muse, mutect2, varscan2
- ADAM23 | c.2337C>A p.P779= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs571615571, COSV52217714; called by muse, varscan2
- AMER3 | c.1548C>A p.P516= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs1319690380; called by muse, mutect2, varscan2
- ANKRD33B | c.1242G>C p.R414= | Silent (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- AP1G1 | c.570C>T p.V190= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- APOBEC3F | c.117G>A p.V39= | Silent (SNP) | VAF 30/358 reads (8%) | catalogued as COSV100415284; called by muse, mutect2
- ARAP3 | c.213G>T p.L71= | Silent (SNP) | VAF 48/164 reads (29%) | called by muse, mutect2, varscan2
- ATAD3B | c.429C>T p.A143= (on ENST00000308647; = p.A249= on NM_031921.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- AXDND1 | c.825G>T p.V275= | Silent (SNP) | VAF 90/214 reads (42%) | called by muse, mutect2, varscan2
- BRD9 | c.1596G>A p.Q532= | Silent (SNP) | VAF 32/442 reads (7%) | called by muse, mutect2
- BRINP1 | c.1878T>A p.P626= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV99776462, COSV99777042; called by muse, mutect2, varscan2
- BUB3 | c.114C>G p.S38= | Silent (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2, varscan2
- C1QL2 | c.447G>A p.A149= | Silent (SNP) | VAF 82/281 reads (29%) | called by muse, mutect2, varscan2
- C20orf96 | c.366C>T p.L122= (on ENST00000360321 / NM_153269.3; = p.L121= on NM_080571.1) | Silent (SNP) | VAF 31/279 reads (11%) | called by muse, mutect2, varscan2
- CABP2 | c.618C>T p.D206= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as rs1484621190, COSV53708231; called by muse, mutect2, varscan2
- CALCOCO1 | c.588G>A p.T196= | Silent (SNP) | VAF 42/498 reads (8%) | catalogued as rs144845004; called by muse, mutect2
- CBLN4 | c.453G>T p.A151= | Silent (SNP) | VAF 30/279 reads (11%) | called by muse, mutect2, varscan2
- CCDC168 | c.14673G>A p.R4891= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- CCER1 | c.111C>T p.S37= | Silent (SNP) | VAF 38/289 reads (13%) | called by muse, mutect2, varscan2
- CD84 | c.996C>T p.D332= (on ENST00000311224 / NM_001184879.2; = p.D315= on NM_003874.4) | Silent (SNP) | VAF 75/258 reads (29%) | called by muse, mutect2, varscan2
- CDKN2AIPNL | c.138C>A p.R46= | Silent (SNP) | VAF 45/241 reads (19%) | called by muse, mutect2, varscan2
- CEP131 | c.1734G>T p.L578= (on ENST00000269392 / NM_001319228.2; = p.L575= on NM_014984.4) | Silent (SNP) | VAF 35/370 reads (9%) | called by muse, mutect2, varscan2
- CEP135 | c.861G>T p.L287= | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2
- CFAP46 | c.1251G>A p.L417= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs915842697; called by muse, mutect2, varscan2
- CFAP52 | c.1395C>A p.S465= | Silent (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- CHAT | c.1116C>T p.S372= | Silent (SNP) | VAF 61/593 reads (10%) | called by muse, mutect2, varscan2
- CHRND | c.18G>C p.L6= | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- CHST3 | c.531G>A p.G177= | Silent (SNP) | VAF 116/779 reads (15%) | called by muse, mutect2, varscan2
- COL11A1 | c.5119C>A p.R1707= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs757608461, COSV62179966, COSV62203151; called by muse, mutect2, varscan2
- COL12A1 | c.7311C>G p.S2437= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV59400696; called by muse, mutect2
- COL24A1 | c.2826T>A p.G942= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- COL9A2 | c.498G>T p.L166= | Silent (SNP) | VAF 95/288 reads (33%) | called by muse, mutect2, varscan2
- CPED1 | c.411A>T p.L137= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- CPNE7 | c.1215C>T p.I405= | Silent (SNP) | VAF 32/269 reads (12%) | called by muse, mutect2, varscan2
- CPOX | c.390C>T p.F130= | Silent (SNP) | VAF 56/228 reads (25%) | called by muse, varscan2
- CSMD3 | c.9822A>T p.V3274= (on ENST00000297405 / NM_001363185.1; = p.V3105= on NM_052900.3) | Silent (SNP) | VAF 54/302 reads (18%) | catalogued as COSV52209229; called by muse, mutect2, varscan2
- CT47B1 | c.219C>G p.A73= | Silent (SNP) | VAF 307/660 reads (47%) | catalogued as COSV64891143; called by muse, mutect2, varscan2
- CTF1 | c.600G>A p.S200= | Silent (SNP) | VAF 42/218 reads (19%) | catalogued as rs1026759136; called by muse, mutect2, varscan2
- CUX2 | c.2187G>A p.E729= | Silent (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.306C>A p.I102= | Silent (SNP) | VAF 70/360 reads (19%) | called by muse, mutect2, varscan2
- DDX39A | c.840C>G p.L280= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV54391403; called by muse, mutect2, varscan2
- DIAPH1 | c.2205C>T p.G735= | Silent (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- DNAI2 | c.912G>T p.V304= | Silent (SNP) | VAF 194/420 reads (46%) | called by muse, mutect2, varscan2
- DOK6 | c.774C>A p.S258= | Silent (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- DYTN | c.1485T>A p.V495= | Silent (SNP) | VAF 68/420 reads (16%) | called by muse, mutect2, varscan2
- ECE1 | c.207G>T p.L69= | Silent (SNP) | VAF 69/426 reads (16%) | called by muse, mutect2, varscan2
- EEF1B2 | c.576A>T p.V192= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- EP300 | c.3930G>A p.L1310= | Silent (SNP) | VAF 28/347 reads (8%) | called by muse, mutect2
- ERBB4 | c.318T>A p.R106= | Silent (SNP) | VAF 15/268 reads (6%) | called by muse, mutect2
- FAM120C | c.2929C>A p.R977= | Silent (SNP) | VAF 62/190 reads (33%) | called by muse, mutect2, varscan2
- FCGBP | c.600G>T p.V200= | Silent (SNP) | VAF 93/185 reads (50%) | called by muse, mutect2, varscan2
- FCRL3 | c.1428C>T p.P476= | Silent (SNP) | VAF 120/270 reads (44%) | catalogued as rs1468155648, COSV100943017, COSV63840188; called by muse, mutect2, varscan2
- FECH | c.456C>T p.P152= | Silent (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- FHL1 | c.420C>T p.S140= | Silent (SNP) | VAF 103/426 reads (24%) | called by muse, mutect2, varscan2
- FLG | c.8379C>T p.S2793= | Silent (SNP) | VAF 251/2179 reads (12%) | catalogued as rs747057114, COSV64240050, COSV64240779; called by muse, mutect2, varscan2
- FLNC | c.7761C>A p.P2587= | Silent (SNP) | VAF 67/219 reads (31%) | called by muse, mutect2, varscan2
- FN3K | c.324A>C p.A108= | Silent (SNP) | VAF 40/556 reads (7%) | called by muse, mutect2
- GALK1 | c.498C>T p.R166= | Silent (SNP) | VAF 48/224 reads (21%) | catalogued as rs763880577; called by muse, mutect2, varscan2
- GAS2L2 | c.417G>T p.V139= | Silent (SNP) | VAF 117/258 reads (45%) | catalogued as rs781922164; called by muse, mutect2, varscan2
- GAS8 | c.60G>T p.G20= | Silent (SNP) | VAF 20/201 reads (10%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1269C>T p.P423= | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as COSV101004208; called by muse, mutect2
- GIPR | c.741C>T p.L247= | Silent (SNP) | VAF 80/1404 reads (6%) | catalogued as COSV99624748; called by muse, mutect2
- GMPPB | c.1008C>A p.L336= (on ENST00000308388 / NM_021971.4; = p.L363= on NM_013334.3) | Silent (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2
- GNAT1 | c.27G>A p.E9= | Silent (SNP) | VAF 49/251 reads (20%) | catalogued as COSV104372303; called by muse, mutect2, varscan2
- GRIP1 | c.3114G>A p.G1038= (on ENST00000359742 / NM_001379345.1; = p.G986= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 175/279 reads (63%) | called by muse, mutect2, varscan2
- GRK3 | c.1536C>T p.V512= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs749382880; called by muse, mutect2, varscan2
- GRM6 | c.24G>A p.R8= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- GSC | c.186G>A p.V62= | Silent (SNP) | VAF 94/223 reads (42%) | called by muse, mutect2, varscan2
- HELZ2 | c.3861G>C p.L1287= (on ENST00000467148 / NM_001037335.2; = p.L718= on NM_033405.3) | Silent (SNP) | VAF 39/197 reads (20%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.528T>G p.T176= (on ENST00000394468 / NM_001039372.4; = p.T164= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/259 reads (27%) | called by muse, mutect2, varscan2
- HMCN1 | c.11865T>A p.L3955= | Silent (SNP) | VAF 65/268 reads (24%) | called by muse, mutect2, varscan2
- HPS5 | c.690G>T p.G230= (on ENST00000349215 / NM_181507.2; = p.G116= on NM_007216.4) | Silent (SNP) | VAF 67/137 reads (49%) | catalogued as COSV62540412; called by muse, mutect2, varscan2
- HS3ST4 | c.156C>T p.L52= | Silent (SNP) | VAF 18/325 reads (6%) | called by muse, mutect2
- HSPA2 | c.534G>A p.T178= | Silent (SNP) | VAF 46/468 reads (10%) | catalogued as rs372664375, COSV99905147; called by muse, mutect2
- IGKV3-15 | c.204C>A p.I68= | Silent (SNP) | VAF 172/1001 reads (17%) | catalogued as rs755211568; called by muse, mutect2, varscan2
- INCA1 | c.171G>A p.L57= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs967835311; called by muse, mutect2, varscan2
- INSC | c.762C>A p.T254= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV65412910; called by muse, mutect2
- IQSEC2 | c.756A>T p.P252= (on ENST00000642864 / NM_001111125.3; = p.P47= on NM_015075.2) | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2
- IRX1 | c.1392G>A p.L464= | Silent (SNP) | VAF 36/606 reads (6%) | called by muse, mutect2
- ITPKB | c.2796C>G p.L932= | Silent (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- KDM4D | c.516A>T p.I172= | Silent (SNP) | VAF 137/221 reads (62%) | called by muse, mutect2, varscan2
- KIAA0930 | c.462G>A p.E154= (on ENST00000336156 / NM_001009880.2; = p.E159= on NM_015264.2) | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs780023552, COSV52663200; called by muse, mutect2
- KIAA1217 | c.399G>T p.L133= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- KIF16B | c.489G>T p.R163= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- KNOP1 | c.843C>T p.I281= | Silent (SNP) | VAF 42/191 reads (22%) | catalogued as rs750255844, COSV54927105; called by muse, mutect2, varscan2
- KRT4 | c.582C>G p.V194= | Silent (SNP) | VAF 66/732 reads (9%) | called by muse, mutect2
- LAMA4 | c.3888G>A p.K1296= (on ENST00000230538 / NM_001105206.3; = p.K1289= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2, varscan2
- LBP | c.954C>G p.T318= | Silent (SNP) | VAF 85/352 reads (24%) | called by muse, mutect2, varscan2
- LEUTX | c.258T>G p.R86= | Silent (SNP) | VAF 102/204 reads (50%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.1431G>A p.E477= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- LRRN4 | c.1782G>T p.T594= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- MADCAM1 | c.996G>T p.L332= | Silent (SNP) | VAF 81/216 reads (38%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1845C>A p.A615= | Silent (SNP) | VAF 80/125 reads (64%) | catalogued as COSV100026254; called by muse, mutect2, varscan2
- MALRD1 | c.3582C>T p.L1194= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- MDN1 | c.6210G>T p.V2070= | Silent (SNP) | VAF 128/564 reads (23%) | called by muse, mutect2, varscan2
- MEAK7 | c.804G>T p.L268= | Silent (SNP) | VAF 115/264 reads (44%) | catalogued as COSV59145253; called by muse, mutect2, varscan2
- MEGF11 | c.285C>T p.S95= | Silent (SNP) | VAF 39/176 reads (22%) | catalogued as rs878944232, COSV99987805; called by muse, mutect2, varscan2
- MKRN3 | c.1275C>A p.G425= | Silent (SNP) | VAF 40/180 reads (22%) | called by muse, mutect2, varscan2
- MPZL1 | c.342C>T p.D114= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- MROH9 | c.696G>A p.K232= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV100882973, COSV100883129; called by muse, mutect2, varscan2
- MRPS21 | c.165A>G p.E55= | Silent (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- MRTFA | c.1080C>T p.A360= | Silent (SNP) | VAF 76/261 reads (29%) | catalogued as rs1392573674, COSV62933382; called by muse, varscan2
- MSR1 | c.636C>A p.I212= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.6579C>A p.S2193= | Silent (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- MUC22 | c.300C>T p.D100= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- MUCL3 | c.900C>A p.S300= | Silent (SNP) | VAF 66/278 reads (24%) | called by muse, mutect2, varscan2
- MYH13 | c.4104C>T p.A1368= | Silent (SNP) | VAF 66/434 reads (15%) | catalogued as rs377365193; called by muse, mutect2, varscan2
- MYO18B | c.6810G>T p.L2270= | Silent (SNP) | VAF 49/163 reads (30%) | called by muse, mutect2, varscan2
- MYOM2 | c.1086C>A p.G362= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV50718277; called by muse, mutect2, varscan2
- NBEA | c.4857T>C p.H1619= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- NHLRC1 | c.468A>G p.S156= | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as CD033859, COSV100513588; called by muse, mutect2, varscan2
- NMBR | c.1060C>T p.L354= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- NTF4 | c.366C>A p.G122= | Silent (SNP) | VAF 60/276 reads (22%) | called by muse, mutect2, varscan2
- NUTM1 | c.1308G>T p.L436= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs749670673; called by muse, mutect2, varscan2
- OR10G3 | c.837C>T p.A279= | Silent (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- OR10K1 | c.904C>A p.R302= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV56870768, COSV99193382; called by muse, mutect2, varscan2
- OR10K2 | c.207T>A p.S69= | Silent (SNP) | VAF 99/323 reads (31%) | called by muse, mutect2, varscan2
- OR10X1 | c.180C>T p.I60= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as COSV100936618; called by muse, mutect2, varscan2
- OR4P4 | c.369C>T p.A123= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1274808152; called by muse, mutect2, varscan2
- OR7E24 | c.927C>T p.S309= | Silent (SNP) | VAF 30/171 reads (18%) | called by muse, mutect2, varscan2
- OR9G4 | c.861T>C p.P287= | Silent (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- PARK7 | c.303G>A p.L101= | Silent (SNP) | VAF 66/383 reads (17%) | called by muse, mutect2, varscan2
- PCDH10 | c.1800C>T p.L600= | Silent (SNP) | VAF 53/232 reads (23%) | catalogued as COSV99993195; called by muse, mutect2, varscan2
- PCDH15 | c.1239C>A p.T413= | Silent (SNP) | VAF 49/249 reads (20%) | catalogued as rs768703592; called by muse, mutect2, varscan2
- PCDHA9 | c.474C>G p.S158= | Silent (SNP) | VAF 114/369 reads (31%) | catalogued as rs781916641, COSV65325536; called by muse, mutect2, varscan2
- PDYN | c.366G>A p.L122= | Silent (SNP) | VAF 83/599 reads (14%) | called by muse, mutect2, varscan2
- PDZD2 | c.7455G>C p.L2485= | Silent (SNP) | VAF 36/416 reads (9%) | catalogued as COSV56854914; called by muse, mutect2
- PGM5 | c.1518C>A p.I506= | Silent (SNP) | VAF 73/150 reads (49%) | called by muse, mutect2, varscan2
- PIGG | c.2799G>T p.T933= (on ENST00000453061 / NM_001127178.3; = p.T925= on NM_017733.4) | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV99573659; called by muse, mutect2, varscan2
- PLEKHG2 | c.357G>A p.R119= | Silent (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- POU5F2 | c.81G>A p.L27= | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- PREX1 | c.3456C>A p.A1152= | Silent (SNP) | VAF 145/499 reads (29%) | called by muse, mutect2, varscan2
- PRR23B | c.738G>T p.A246= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV61493405; called by muse, mutect2, varscan2
- PTCH2 | c.3135C>A p.G1045= | Silent (SNP) | VAF 128/435 reads (29%) | called by muse, mutect2, varscan2
- PTPRH | c.2304C>T p.L768= | Silent (SNP) | VAF 45/261 reads (17%) | catalogued as rs1437923251; called by muse, mutect2, varscan2
- PTPRN | c.96C>T p.C32= | Silent (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- RANBP3 | c.618A>T p.A206= | Silent (SNP) | VAF 35/96 reads (36%) | called by muse, mutect2, varscan2
- RBFOX1 | c.159A>T p.T53= | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- REPS1 | c.525A>G p.P175= | Silent (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- RGL4 | c.240C>T p.P80= | Silent (SNP) | VAF 15/228 reads (7%) | called by muse, mutect2
- RGPD3 | c.60G>T p.P20= | Silent (SNP) | VAF 53/466 reads (11%) | catalogued as rs778699719; called by muse, mutect2, varscan2
- RHBDF2 | c.2013C>T p.L671= | Silent (SNP) | VAF 14/167 reads (8%) | catalogued as rs777681843; called by muse, mutect2
- RNF150 | c.744G>T p.L248= | Silent (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- RPS5 | c.402G>A p.V134= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as COSV52192031; called by muse, mutect2, varscan2
- RPS6KA5 | c.447C>T p.F149= | Silent (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- RREB1 | c.1548G>T p.R516= | Silent (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- RTL9 | c.2637A>T p.T879= | Silent (SNP) | VAF 119/237 reads (50%) | called by muse, mutect2, varscan2
- RUNDC3A | c.504C>A p.T168= | Silent (SNP) | VAF 16/271 reads (6%) | called by muse, mutect2
- RXFP3 | c.610C>A p.R204= | Silent (SNP) | VAF 138/424 reads (33%) | catalogued as rs754795557, COSV57506270; called by muse, mutect2, varscan2
- SAMD9L | c.741A>T p.G247= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- SCN11A | c.3537G>T p.L1179= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- SCN2A | c.1830T>C p.S610= | Silent (SNP) | VAF 36/273 reads (13%) | called by muse, mutect2, varscan2
- SERPINA4 | c.1038T>C p.A346= | Silent (SNP) | VAF 85/221 reads (38%) | called by muse, mutect2, varscan2
- SERPINB2 | c.1155C>G p.G385= | Silent (SNP) | VAF 20/50 reads (40%) | called by mutect2, varscan2
- SETD1A | c.4614C>T p.S1538= | Silent (SNP) | VAF 71/169 reads (42%) | catalogued as rs756766457; called by muse, mutect2, varscan2
- SGSM1 | c.2361G>A p.L787= (on ENST00000400359 / NM_001039948.4; = p.L726= on NM_133454.3) | Silent (SNP) | VAF 59/320 reads (18%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4293C>T p.H1431= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs374770438; called by muse, mutect2, varscan2
- SLC27A3 | c.870C>A p.A290= (on ENST00000271857; = p.A162= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- SLITRK4 | c.1818C>T p.P606= | Silent (SNP) | VAF 78/143 reads (55%) | catalogued as COSV62026634; called by muse, mutect2, varscan2
- SLITRK5 | c.2523G>A p.R841= | Silent (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- SMIM23 | c.84C>T p.S28= | Silent (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- SOX1 | c.192G>T p.G64= | Silent (SNP) | VAF 159/304 reads (52%) | catalogued as COSV58378315; called by muse, mutect2, varscan2
- SPTA1 | c.6081C>T p.H2027= | Silent (SNP) | VAF 116/388 reads (30%) | catalogued as COSV63751647; called by muse, mutect2, varscan2
- SPTBN5 | c.8913C>T p.A2971= | Silent (SNP) | VAF 44/311 reads (14%) | catalogued as rs779291221; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.294G>T p.L98= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100603003; called by muse, mutect2, varscan2
- SVIL | c.3096G>A p.R1032= (on ENST00000355867 / NM_021738.3; = p.R606= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV63443589; called by muse, mutect2
- TAF1 | c.4458G>T p.A1486= (on ENST00000373790 / NM_138923.4; = p.A1507= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV52125753; called by muse, mutect2, varscan2
- TAF6 | c.609G>C p.G203= | Silent (SNP) | VAF 49/165 reads (30%) | called by muse, mutect2, varscan2
- TEKT4 | c.216G>T p.L72= | Silent (SNP) | VAF 131/261 reads (50%) | called by muse, mutect2, varscan2
- TMEM132C | c.1605G>C p.T535= | Silent (SNP) | VAF 27/260 reads (10%) | catalogued as COSV59433699; called by muse, mutect2, varscan2
- TOP1MT | c.24G>T p.R8= | Silent (SNP) | VAF 48/593 reads (8%) | called by muse, mutect2
- TPSD1 | c.393G>C p.L131= | Silent (SNP) | VAF 52/337 reads (15%) | catalogued as COSV99273708; called by muse, mutect2, varscan2
- TRIM27 | c.867G>A p.E289= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs757070636; called by muse, mutect2, varscan2
- TTN | c.55689G>A p.V18563= (on ENST00000591111; = p.V11139= on NM_003319.4) | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs897086744; called by muse, mutect2, varscan2
- UAP1 | c.246G>A p.R82= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- UNC45B | c.2604C>T p.G868= | Silent (SNP) | VAF 75/353 reads (21%) | called by muse, mutect2, varscan2
- USP29 | c.1983G>T p.V661= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV99518309; called by muse, mutect2, varscan2
- VRTN | c.1074C>A p.G358= | Silent (SNP) | VAF 87/216 reads (40%) | called by muse, mutect2, varscan2
- WDFY4 | c.6537G>A p.K2179= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV99630076; called by muse, mutect2, varscan2
- WDR24 | c.1650G>T p.A550= (on ENST00000248142; = p.A420= on NM_032259.4) | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs772843694, COSV50196971; called by muse, mutect2, varscan2
- WNT3A | c.769C>A p.R257= | Silent (SNP) | VAF 73/242 reads (30%) | called by muse, mutect2, varscan2
- WWC3 | c.2242C>A p.R748= | Silent (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- XDH | c.342G>A p.G114= | Silent (SNP) | VAF 235/471 reads (50%) | catalogued as rs377004053; called by muse, mutect2, varscan2
- XKR7 | c.1158C>A p.L386= | Silent (SNP) | VAF 76/231 reads (33%) | called by muse, mutect2, varscan2
- ZCRB1 | c.417A>G p.K139= | Silent (SNP) | VAF 63/117 reads (54%) | called by muse, mutect2, varscan2
- ZFHX3 | c.7998G>T p.P2666= | Silent (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2
- ZNF208 | c.2760A>G p.E920= | Silent (SNP) | VAF 20/248 reads (8%) | called by muse, mutect2
- ZNF469 | c.4941C>G p.A1647= (on ENST00000437464; = p.A1675= on NM_001367624.2) | Silent (SNP) | VAF 181/452 reads (40%) | called by muse, mutect2, varscan2
- ZNF516 | c.258G>T p.T86= | Silent (SNP) | VAF 126/315 reads (40%) | called by muse, mutect2, varscan2
- ZNF749 | c.912G>C p.G304= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- A4GALT | c.*148A>T | 3'UTR (SNP) | VAF 66/678 reads (10%) | called by muse, mutect2
- AARS1 | c.817-21C>A | Intron (SNP) | VAF 54/343 reads (16%) | called by muse, mutect2, varscan2
- ABCC13 | n.3876G>C | RNA (SNP) | VAF 16/78 reads (21%) | catalogued as rs1415938661; called by muse, mutect2, varscan2
- AC011525.1 | n.850C>A | RNA (SNP) | VAF 77/139 reads (55%) | called by muse, mutect2, varscan2
- AC068633.1 | n.15T>C | RNA (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- AC099548.2 | n.1352A>T | RNA (SNP) | VAF 40/246 reads (16%) | called by mutect2, varscan2
- AC116351.1 | n.1319C>A | RNA (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- AGAP12P | n.1916C>A | RNA (SNP) | VAF 273/1465 reads (19%) | called by mutect2, varscan2
- AGAP12P | n.1915C>A | RNA (SNP) | VAF 292/1581 reads (18%) | called by muse, mutect2, varscan2
- AKAP9 | c.5698-2968G>A | Intron (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- AL035696.1 | n.307C>A | RNA (SNP) | VAF 119/259 reads (46%) | called by muse, mutect2, varscan2
- AMACR | c.-23T>A | 5'UTR (SNP) | VAF 125/387 reads (32%) | called by muse, mutect2, varscan2
- ANK2 | c.85-57015A>C | Intron (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503921 C>T | 5'Flank (SNP) | VAF 7/49 reads (14%) | catalogued as rs745705097; called by muse, mutect2, varscan2
- ARMC6 | c.29+3343G>C | Intron (SNP) | VAF 171/247 reads (69%) | called by muse, mutect2, varscan2
- CD320 | c.-8G>A | 5'UTR (SNP) | VAF 183/394 reads (46%) | catalogued as rs1482476829; called by muse, mutect2, varscan2
- CGREF1 | c.-11-66A>T | Intron (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2, varscan2
- CLEC12B | c.680+9C>A | Intron (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- CNTNAP3P2 | n.179G>C | RNA (SNP) | VAF 17/141 reads (12%) | called by mutect2, varscan2
- CRISP3 | c.-10C>T | 5'UTR (SNP) | VAF 18/108 reads (17%) | called by muse, varscan2
- DCHS2 | n.3469A>G | RNA (SNP) | VAF 82/310 reads (26%) | called by muse, mutect2, varscan2
- DCHS2 | n.2420G>A | RNA (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2, varscan2
- DMPK | c.*23C>T | 3'UTR (SNP) | VAF 123/1008 reads (12%) | called by muse, mutect2, varscan2
- EI24P4 | n.873C>G | RNA (SNP) | VAF 48/178 reads (27%) | called by muse, mutect2, varscan2
- EPS8 | c.1101+33C>G | Intron (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- ERCC8 | c.276-33C>T | Intron (SNP) | VAF 12/102 reads (12%) | catalogued as rs1424141638; called by muse, mutect2, varscan2
- ESPNP | n.1660C>A | RNA (SNP) | VAF 38/791 reads (5%) | called by muse, mutect2
- FCGR2B | c.761-40C>A | Intron (SNP) | VAF 73/147 reads (50%) | catalogued as rs758059520; called by muse, mutect2, varscan2
- FOXP2 | c.*1838G>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- GK5 | c.411+24G>T | Intron (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
55 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 55 other) are not listed here.
